Somatic mutation profile of tumor specimen TCGA-AB-2857-03B (aliquot TCGA-AB-2857-03B-01W-0728-08) from TCGA case TCGA-AB-2857, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, M6 type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.5 years (19,905 days).
Specimen TCGA-AB-2857-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e50dbfa5-1de6-418c-b629-494c9981a993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2857-11B (Solid Tissue Normal), aliquot TCGA-AB-2857-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf40e170-cc5b-4fb8-882f-c3ac0ec92bda

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373473841; called by muse, mutect2, varscan2
- CDH16 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs756379474, COSV55335085; called by muse, mutect2, varscan2
- COL25A1 | c.861+1G>A p.X287_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV67646931; called by muse, mutect2, varscan2
- CSMD3 | c.2729G>A p.G910E (on ENST00000297405 / NM_001363185.1; = p.G806E on NM_052900.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113479; called by muse, mutect2, varscan2
- DNAH7 | c.10570C>G p.P3524A | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100414721; called by muse, mutect2
- DOCK10 | c.1892G>A p.C631Y | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs745882059, COSV51351716; called by muse, mutect2, varscan2
- FAM71A | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 47/284 reads (17%) | catalogued as rs767932931, COSV54234758; called by muse, mutect2, varscan2
- GATA2 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003275; called by muse, mutect2, varscan2
- GRIK1 | c.2624A>T p.Y875F | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100516487; called by muse, mutect2
- GUCY1A2 | c.2167G>A p.G723S | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1259379286, COSV56489596; called by muse, mutect2
- HOXA9 | c.570dup p.I191Hfs*5 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | catalogued as rs1307227987; called by pindel, varscan2
- JMJD1C | c.4261T>C p.S1421P | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as COSV59513182; called by muse, mutect2, varscan2
- MICAL2 | c.1784C>G p.T595R | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV56317090; called by muse, mutect2, varscan2
- MMP25 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60678771; called by muse, mutect2, varscan2
- PCDHA3 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs781899440, COSV100793319, COSV100793323, COSV63544830; called by muse, mutect2
- SCN1A | c.1342A>G p.I448V | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57661917, COSV57675774; called by muse, mutect2, varscan2
- SPATA31A1 | c.2051G>A p.R684K | Missense Mutation (SNP) | VAF 107/966 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2
- BACH1 | c.2023C>A p.R675= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV54517496, COSV54519855; called by muse, mutect2, varscan2
- COX10 | c.1089C>T p.A363= | Silent (SNP) | VAF 87/189 reads (46%) | catalogued as rs774320292, COSV55402619; called by muse, mutect2, varscan2
- KRT37 | c.1134C>T p.A378= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as rs751478916, COSV56657018; called by muse, mutect2, varscan2
- KRT75 | c.237C>T p.S79= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV52871252; called by muse, mutect2, varscan2
- ZNF473 | c.2271T>G p.P757= | Silent (SNP) | VAF 38/250 reads (15%) | catalogued as COSV54522173; called by muse, mutect2, varscan2
